Somatic mutation profile of tumor specimen TCGA-CN-5373-01A (aliquot TCGA-CN-5373-01A-01D-1434-08) from TCGA case TCGA-CN-5373, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 55.1 years (20,143 days).
Specimen TCGA-CN-5373-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90cc7d46-a51d-4b66-98e5-6e51be3ed146.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-5373-10A (Blood Derived Normal), aliquot TCGA-CN-5373-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/184507d2-9822-413b-a360-98c2f68b5168

The open-access MAF lists 157 somatic variants for this specimen: 116 protein-altering or splice-affecting, 35 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 35, Nonsense Mutation 13, Intron 4, Frame Shift Ins 4, Frame Shift Del 4, In Frame Ins 1, Nonstop Mutation 1, 5'Flank 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- IDUA | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as rs1356329915, COSV99925632; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 40/124 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 34/83 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AK2 | c.359C>G p.P120R (on ENST00000354858; = p.P162R on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/530 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100709792; called by muse, mutect2, varscan2
- ALKBH4 | c.907T>A p.*303Rext*36 | Nonstop Mutation (SNP) | VAF 22/123 reads (18%) | catalogued as COSV99479124; called by muse, mutect2, varscan2
- ALKBH5 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 83/444 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs775474036, COSV101213227; called by muse, mutect2, varscan2
- ANKRD17 | c.3413A>T p.N1138I | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV100428477; called by muse, mutect2, varscan2
- AOC2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs373389718, COSV99513467; called by muse, mutect2, varscan2
- ARHGEF6 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51690345, COSV51697349, COSV99166339; called by muse, mutect2, varscan2
- ASB3 | c.1114G>C p.G372R | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55075843, COSV99711709; called by muse, mutect2, varscan2
- ASIC2 | c.808A>G p.T270A | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV99859177; called by muse, varscan2
- ASTN1 | c.2074C>T p.L692F | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV99920309; called by muse, mutect2
- ATL3 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776571949, COSV100219637; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATM | c.3157G>A p.D1053N | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99587052; called by muse, mutect2, varscan2
- BSPRY | c.278C>A p.P93Q | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100949481; called by muse, mutect2
- C16orf71 | c.192C>A p.D64E | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100172758; called by muse, mutect2, varscan2
- C16orf72 | c.743A>G p.N248S | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs763474218, COSV100588951; called by muse, mutect2, varscan2
- C17orf67 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.923); catalogued as rs766096754, COSV101190892; called by muse, mutect2, varscan2
- C19orf18 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 57/226 reads (25%) | catalogued as rs1457181135, COSV100071629; called by muse, mutect2, varscan2
- CD27 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56950019, COSV99869792; called by muse, varscan2
- CD52 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.666); catalogued as rs141117966; called by muse, mutect2, varscan2
- CDH12 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101201108; called by muse, mutect2, varscan2
- CHD3 | c.4597T>C p.S1533P | Missense Mutation (SNP) | VAF 76/397 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100390622; called by muse, mutect2, varscan2
- CLPX | c.160C>T p.L54F | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100269278; called by muse, mutect2, varscan2
- CNTN6 | c.2644T>C p.Y882H | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100610006; called by muse, mutect2, varscan2
- CT55 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 54/187 reads (29%) | catalogued as rs782749026, COSV52279257; called by muse, mutect2, varscan2
- DCAF4L2 | c.167G>T p.R56M | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100150465, COSV60477058; called by muse, mutect2, varscan2
- DHX34 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs149967464, COSV60898381; called by muse, mutect2, varscan2
- DLG2 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 44/299 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as COSV101070251, COSV65878993; called by muse, mutect2, varscan2
- DROSHA | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV60784463; called by muse, mutect2, varscan2
- DVL3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs1432120023, COSV100493509; called by muse, mutect2, varscan2
- DYRK1B | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100546406; called by muse, mutect2, varscan2
- EDEM3 | c.956A>G p.Y319C | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1160330851, COSV100544833; called by muse, mutect2, varscan2
- EGFL8 | c.157T>C p.Y53H | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as COSV100246783; called by muse, mutect2, varscan2
- EP400 | c.8002C>T p.R2668* | Nonsense Mutation (SNP) | VAF 33/157 reads (21%) | catalogued as rs1195965212, COSV57769745; called by muse, mutect2, varscan2
- ETNPPL | c.1099A>T p.I367F | Missense Mutation (SNP) | VAF 74/290 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV56597063, COSV99624905; called by muse, mutect2, varscan2
- F8 | c.1094A>G p.Y365C | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs375241473, CM020415, COSV64269740; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- FGD1 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64309835; called by muse, mutect2, varscan2
- FGD3 | c.463C>G p.P155A | Missense Mutation (SNP) | VAF 53/405 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV100490365; called by muse, mutect2, varscan2
- FLG | c.9302C>G p.S3101* | Nonsense Mutation (SNP) | VAF 122/681 reads (18%) | catalogued as COSV100910440, COSV64251243; called by muse, mutect2, varscan2
- GABRA5 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.685); catalogued as COSV59475690; called by muse, mutect2, varscan2
- GATM | c.877A>G p.I293V | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101188088; called by muse, mutect2, varscan2
- GH2 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV100236793, COSV60427496; called by muse, mutect2, varscan2
- GPRC6A | c.925A>G p.T309A | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV100113974; called by muse, mutect2, varscan2
- HSD17B11 | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs760969818, COSV100839528; called by muse, mutect2, varscan2
- HTR1F | c.30C>G p.N10K | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.065); catalogued as COSV100137921; called by muse, mutect2, varscan2
- IPO13 | c.1236G>A p.W412* | Nonsense Mutation (SNP) | VAF 37/136 reads (27%) | catalogued as COSV100961034; called by muse, mutect2, varscan2
- ITPRID1 | c.854T>C p.V285A | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100085550; called by muse, mutect2, varscan2
- KCNA1 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 85/430 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1352539698, COSV66836946; called by muse, mutect2, varscan2
- KDM4D | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 34/130 reads (26%) | catalogued as COSV100624123; called by muse, mutect2, varscan2
- KLF3 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 74/308 reads (24%) | catalogued as COSV54711752; called by muse, mutect2, varscan2
- KRT5 | c.229_230insTTGAT p.S77Ifs*76 | Frame Shift Ins (INS) | VAF 30/152 reads (20%) | catalogued as COSV99357767; called by pindel, varscan2
- LEXM | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64022732, COSV64022804; called by muse, mutect2, varscan2
- LOXL3 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99283905; called by muse, mutect2
- LYST | c.7487T>C p.L2496P | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101088014; called by muse, mutect2, varscan2
- MAMLD1 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99475494; called by muse, mutect2, varscan2
- MCTP1 | c.2435T>C p.V812A | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.536); catalogued as COSV100386123; called by muse, varscan2
- MDH1B | c.1316G>A p.S439N | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs761068485, COSV100982122; called by muse, mutect2, varscan2
- MYH8 | c.2977G>T p.A993S | Missense Mutation (SNP) | VAF 64/301 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV101238120, COSV67962510; called by muse, mutect2, varscan2
- NAALADL1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV100367913; called by muse, mutect2, varscan2
- NELFE | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as rs555434140, COSV100952571; called by muse, mutect2, varscan2
- NEXMIF | c.786G>C p.E262D | Missense Mutation (SNP) | VAF 10/326 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50022215, COSV99279478; called by muse, mutect2
- NEXMIF | c.785A>C p.E262A | Missense Mutation (SNP) | VAF 10/326 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99279483; called by muse, mutect2
- NIPBL | c.3058A>G p.R1020G | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); catalogued as COSV99238554; called by muse, mutect2, varscan2
- NMB | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100850520; called by muse, mutect2, varscan2
- NPHP3 | c.2833C>T p.L945F | Missense Mutation (SNP) | VAF 36/276 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100446574; called by muse, mutect2, varscan2
- OR4N5 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 116/557 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.676); catalogued as COSV100374009; called by muse, mutect2, varscan2
- OR5A2 | c.625A>G p.I209V | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV100119661; called by muse, mutect2, varscan2
- P3H3 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.92); catalogued as rs1242921806, COSV51831998; called by muse, mutect2, varscan2
- PAPPA2 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV100866514; called by muse, mutect2, varscan2
- PASD1 | c.2200G>T p.E734* | Nonsense Mutation (SNP) | VAF 62/354 reads (18%) | catalogued as rs754453250, COSV64855674, COSV64856719; called by muse, mutect2, varscan2
- PAX3 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.233); catalogued as COSV51339632, COSV99286360; called by muse, mutect2, varscan2
- PCDHB2 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV50564064; called by muse, mutect2, varscan2
- PCDHGA1 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 87/309 reads (28%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.01); catalogued as rs776076044, COSV65294924, COSV65295117, COSV65297635; called by muse, mutect2, varscan2
- PCDHGA5 | c.72C>A p.C24* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV53962296, COSV99529675; called by muse, mutect2, varscan2
- PIK3C3 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV100010193; called by muse, mutect2, varscan2
- PKHD1L1 | c.2872G>A p.D958N | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV65743124; called by muse, mutect2, varscan2
- PLCG1 | c.857G>T p.R286L | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV54815786, COSV99718436; called by muse, mutect2, varscan2
- PPFIA2 | c.3620A>G p.H1207R | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.215); catalogued as rs1163940378, COSV100331507; called by muse, mutect2, varscan2
- PPP6R1 | c.1036A>G p.M346V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101336938; called by muse, mutect2, varscan2
- PYGB | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.282); catalogued as rs370514593; called by muse, mutect2, varscan2
- RAB3IP | c.172C>T p.R58W (on ENST00000550536 / NM_175623.4; = p.R42W on NM_022456.5) | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs749687711, COSV56085347; called by muse, mutect2, varscan2
- RSPO2 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); catalogued as rs368908416; called by muse, mutect2, varscan2
- SCN4A | c.4783G>A p.A1595T | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs761947899, COSV71127375; called by muse, mutect2, varscan2
- SERINC3 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99667565; called by muse, mutect2, varscan2
- SH2D1A | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.45); catalogued as COSV100758263; called by muse, mutect2, varscan2
- SLIT2 | c.4233T>A p.D1411E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV99880502; called by muse, mutect2, varscan2
- SNX2 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 71/329 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs755031564, COSV65348384; called by muse, mutect2, varscan2
- SNX30 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 64/289 reads (22%) | catalogued as COSV100953732; called by muse, mutect2, varscan2
- SYNE2 | c.3178A>G p.R1060G | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100646566; called by muse, mutect2, varscan2
- SYT1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs868227414, COSV54050678; called by muse, mutect2, varscan2
- TBL1X | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54278658; called by muse, mutect2, varscan2
- TBX15 | c.888C>G p.N296K (on ENST00000369429 / NM_001330677.2; = p.N190K on NM_152380.3) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99253516; called by muse, mutect2, varscan2
- THSD7A | c.1397G>A p.C466Y | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101448527; called by muse, mutect2, varscan2
- TTN | c.17675A>T p.E5892V (on ENST00000591111; = p.E4965V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/163 reads (22%) | PolyPhen probably damaging (0.975); catalogued as COSV60351609; called by muse, mutect2, varscan2
- TTN | c.10823T>A p.V3608E (on ENST00000591111; = p.V3562E on NM_003319.4) | Missense Mutation (SNP) | VAF 86/332 reads (26%) | catalogued as COSV100592516; called by muse, mutect2, varscan2
- TUBG1 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99258370, COSV99258995; called by muse, mutect2, varscan2
- TXNL1 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.352); catalogued as rs770023224, COSV54178147; called by muse, mutect2, varscan2
- WIPI1 | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100048196; called by muse, mutect2, varscan2
- WNT9B | c.103C>G p.P35A | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV99254956; called by muse, mutect2, varscan2
- YWHAB | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/118 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV100803103; called by muse, mutect2, varscan2
- ZNF134 | c.911T>A p.V304D | Missense Mutation (SNP) | VAF 61/285 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV101270695; called by muse, mutect2, varscan2
- ZNF41 | c.1159G>C p.E387Q | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV100491787; called by muse, mutect2, varscan2
- ZNF808 | c.1594C>G p.L532V | Missense Mutation (SNP) | VAF 62/327 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100707769; called by muse, mutect2, varscan2
- ADGRV1 | c.3376dup p.I1126Nfs*11 | Frame Shift Ins (INS) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- CCN2 | c.887dup p.H296Qfs*14 | Frame Shift Ins (INS) | VAF 61/279 reads (22%) | called by mutect2, pindel, varscan2
- IGHV1-45 | c.287G>A p.S96N | Missense Mutation (SNP) | VAF 76/301 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KRT5 | c.88_89dup p.S31Pfs*121 | Frame Shift Ins (INS) | VAF 14/68 reads (21%) | called by pindel, varscan2
- MAML3 | c.1908_1913dup p.Q649_Q650dup | In Frame Ins (INS) | VAF 24/76 reads (32%) | called by mutect2, varscan2
- RIMS2 | c.3883del p.S1295Afs*42 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | called by pindel, varscan2
- SLC25A2 | c.823_833del p.R275Cfs*70 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- SNRPN | c.407del p.G136Dfs*6 | Frame Shift Del (DEL) | VAF 20/108 reads (19%) | called by mutect2, pindel
- TPTE | c.848A>T p.N283I (on ENST00000618007 / NM_199261.4; = p.N265I on NM_199259.4) | Missense Mutation (SNP) | VAF 19/297 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZC2HC1C | c.832del p.S278Afs*55 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | called by mutect2, pindel, varscan2
- ZNF140 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 136/630 reads (22%) | called by muse, mutect2, varscan2
- ADAM33 | c.2328C>T p.P776= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1423288815; called by muse, varscan2
- ATP7A | c.1497C>T p.C499= | Silent (SNP) | VAF 78/359 reads (22%) | catalogued as rs782495317, COSV58449796; called by muse, mutect2, varscan2
- CMYA5 | c.6774C>T p.D2258= | Silent (SNP) | VAF 30/159 reads (19%) | catalogued as rs201918595; called by muse, mutect2, varscan2
- CR1L | c.396C>T p.S132= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as rs370675697; called by muse, mutect2, varscan2
- DAXX | c.810C>T p.R270= | Silent (SNP) | VAF 61/197 reads (31%) | catalogued as COSV56471351; called by muse, mutect2, varscan2
- DDR1 | c.2256C>T p.S752= (on ENST00000324771; = p.S715= on NM_001954.4) | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs1409020721, COSV100240932; called by muse, mutect2, varscan2
- DOCK10 | c.3903G>A p.E1301= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as rs201468439, COSV99287416; called by muse, mutect2, varscan2
- DSCAML1 | c.5403G>A p.R1801= (on ENST00000321322; = p.R1741= on NM_020693.4) | Silent (SNP) | VAF 54/213 reads (25%) | catalogued as COSV100354430; called by muse, mutect2, varscan2
- EML4 | c.2934G>A p.S978= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs147316565; called by muse, mutect2, varscan2
- EPX | c.1113C>T p.F371= | Silent (SNP) | VAF 30/111 reads (27%) | catalogued as COSV56595079; called by muse, mutect2, varscan2
- GCNA | c.1722G>A p.Q574= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs1569442325, COSV101032367; called by muse, mutect2, varscan2
- GEMIN5 | c.1272C>A p.G424= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as COSV99593560; called by muse, mutect2, varscan2
- LHX3 | c.540C>T p.P180= (on ENST00000371748 / NM_178138.6; = p.P185= on NM_014564.5) | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs753634858, COSV100871131; called by muse, mutect2, varscan2
- LRP1B | c.213G>A p.E71= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV101251681; called by muse, mutect2, varscan2
- MAS1L | c.807G>A p.S269= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs574752980, COSV101009635; called by muse, mutect2, varscan2
- MYH13 | c.3666G>A p.E1222= | Silent (SNP) | VAF 31/213 reads (15%) | catalogued as COSV99352092; called by muse, mutect2, varscan2
- NPAS4 | c.537A>T p.G179= | Silent (SNP) | VAF 45/235 reads (19%) | catalogued as COSV100214747; called by muse, mutect2, varscan2
- PAMR1 | c.363C>T p.Y121= | Silent (SNP) | VAF 62/262 reads (24%) | catalogued as rs748163488, COSV53511749; called by muse, mutect2, varscan2
- PCDH12 | c.1084C>T p.L362= | Silent (SNP) | VAF 54/249 reads (22%) | catalogued as COSV99185756; called by muse, mutect2, varscan2
- PCDHA8 | c.1356T>C p.A452= | Silent (SNP) | VAF 45/167 reads (27%) | catalogued as rs781941192, COSV100970405, COSV65339591; called by muse, mutect2, varscan2
- PCDHB11 | c.123C>T p.S41= | Silent (SNP) | VAF 37/166 reads (22%) | catalogued as COSV53376237, COSV99503576; called by muse, mutect2, varscan2
- PCDHGA10 | c.1884C>T p.G628= | Silent (SNP) | VAF 31/143 reads (22%) | catalogued as COSV99529679; called by muse, mutect2, varscan2
- RASIP1 | c.1155G>A p.L385= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs771260766, COSV99710442; called by muse, mutect2, varscan2
- RPS6KA2 | c.1929C>T p.D643= | Silent (SNP) | VAF 46/210 reads (22%) | catalogued as rs149521975; called by muse, mutect2
- SEC24B | c.1809G>A p.V603= | Silent (SNP) | VAF 43/158 reads (27%) | catalogued as rs1490209166, COSV99492794; called by muse, mutect2, varscan2
- SERPIND1 | c.258C>T p.F86= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as COSV99299973; called by muse, mutect2, varscan2
- SLC9A2 | c.2394G>A p.S798= | Silent (SNP) | VAF 54/185 reads (29%) | catalogued as rs1216068801, COSV52129301; called by muse, mutect2, varscan2
- TAS2R41 | c.561C>A p.V187= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as COSV101281467, COSV68765603; called by muse, mutect2, varscan2
- TG | c.7122C>T p.G2374= | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as rs554880708, COSV99598769; called by muse, varscan2
- TG | c.7878G>A p.A2626= | Silent (SNP) | VAF 33/148 reads (22%) | catalogued as rs376481950; called by muse, mutect2, varscan2
- TMEM30B | c.957C>T p.I319= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100855687; called by muse, mutect2, varscan2
- TRIM62 | c.756C>T p.S252= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs776489986, COSV52223778, COSV99357607; called by muse, mutect2, varscan2
- UGT3A2 | c.1281C>A p.I427= | Silent (SNP) | VAF 66/321 reads (21%) | catalogued as COSV99235959; called by muse, mutect2, varscan2
- VWF | c.1404C>T p.G468= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV99777814; called by muse, mutect2, varscan2
- ZNF319 | c.726G>A p.S242= | Silent (SNP) | VAF 45/211 reads (21%) | catalogued as COSV54623789; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502317 A>G | 5'Flank (SNP) | VAF 22/49 reads (45%) | catalogued as rs749945119; called by muse, mutect2, varscan2
- CALCR | c.51+2978C>T | Intron (SNP) | VAF 33/132 reads (25%) | catalogued as rs774519762, COSV64005791, COSV64008954; called by muse, mutect2, varscan2
- IGF2BP2 | c.240-15096C>G | Intron (SNP) | VAF 6/94 reads (6%) | catalogued as COSV99960262; called by muse, mutect2
- NDUFV3 | c.170-5331C>T | Intron (SNP) | VAF 74/274 reads (27%) | catalogued as rs200448757, COSV100446865; called by muse, mutect2, varscan2
- TTN | c.10361-5392del | Intron (DEL) | VAF 39/168 reads (23%) | called by mutect2, pindel, varscan2
- ZNF99 | c.*1079T>A | 3'UTR (SNP) | VAF 61/214 reads (29%) | catalogued as COSV101233672; called by muse, mutect2, varscan2
